CCDI case PBBYMI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/e5676641-90b2-49fc-bd55-f9e61b1821e7

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Sertoli-Leydig cell tumor, poorly differentiated: ICD-O-3 morphology code: 8631/3; Tissue or organ of origin: Ovary; Age at diagnosis: 15.0 years (5,497 days).

Biospecimens (3 samples)
- Sample 0DKO76: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DKO7G: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DKO7I: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
